Somatic mutation profile of tumor specimen TCGA-AB-2908-03A (aliquot TCGA-AB-2908-03A-01W-0745-08) from TCGA case TCGA-AB-2908, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 81.5 years (29,769 days).
Specimen TCGA-AB-2908-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d80e9fd-c994-41e9-a0fd-77cf4477528d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2908-11A (Solid Tissue Normal), aliquot TCGA-AB-2908-11A-01W-0745-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6bc2e16e-d300-4501-ac38-a0b9e75b9933

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNTNAP4 | c.1972G>A p.E658K | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs372054509; called by muse, mutect2, varscan2
- HNRNPF | c.82C>A p.Q28K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.1); catalogued as COSV100562913; called by muse, mutect2, varscan2
- PCDHA8 | c.1852C>A p.P618T | Missense Mutation (SNP) | VAF 45/53 reads (85%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV65326537; called by muse, mutect2, varscan2
- AC092143.1 | c.2261A>G p.E754G | Missense Mutation (SNP) | VAF 3/72 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC22A6 | c.35dup p.V13Cfs*64 | Frame Shift Ins (INS) | VAF 5/38 reads (13%) | called by mutect2, pindel, varscan2
- IKZF3 | c.1419C>T p.C473= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as COSV53102243; called by muse, mutect2, varscan2
- ORAI2 | c.438C>T p.I146= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as rs1324354244, COSV62689977; called by muse, mutect2
